CCDI case PBCKEJ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/fbe0d017-044e-42c9-81e4-ebcb6d8b1506

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.3 years (4,483 days).

Biospecimens (3 samples)
- Sample 0DU3KE: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DU3LM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DU3MI: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
